Gene-level copy-number profile of tumor specimen BLGSP-71-26-00396-01A from CGCI case BLGSP-71-26-00396, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 46.1 years (16,832 days).
Specimen BLGSP-71-26-00396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c144c27c-d544-47fc-9af5-2bb558a43c34.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-26-00396-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,758 have no estimate.
https://portal.gdc.cancer.gov/files/acfb0a6f-1bdf-4501-a59f-9d633ffd6b8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,257; copy number 2: 50,838; copy number 3: 4,287; copy number 4: 465; copy number 5: 15.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,825,207, 2 genes (within-gene range 0–2): MALLP2, MIR4436A.
- chr2:110,513,812–110,577,185, 1 gene: RGPD6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,513,377–158,100,262, 15 genes, copy number 5: FCRL5, FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1.

Autosomal genes at a single copy (total copy number 1): 449. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
